Somatic mutation profile of tumor specimen 1105199 (aliquot 7316UP-743-1105199) from CPTAC case C224967, project CPTAC-3 (Complex Epithelial Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenosquamous carcinoma.
Specimen 1105199: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9ad1d06-5c74-4c54-9361-e10df94ae21f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105291 (Blood Derived Normal), aliquot 7316UP-743-1105291; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aebc7b4-2bb0-452c-b78f-a6c17a8d394f

The open-access MAF lists 224 somatic variants for this specimen: 173 protein-altering or splice-affecting, 36 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 36, Nonsense Mutation 11, Intron 6, Frame Shift Ins 5, Frame Shift Del 5, Splice Site 3, 3'UTR 3, Splice Region 2, 5'Flank 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 74/572 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 233/343 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs779191648; called by muse, mutect2, varscan2
- AC100868.1 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51838929; called by muse, mutect2, varscan2
- AC134980.2 | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 90/141 reads (64%) | catalogued as COSV60906617; called by muse, mutect2, varscan2
- AK5 | c.114G>T p.L38F (on ENST00000354567 / NM_174858.3; = p.L12F on NM_012093.4) | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100481326; called by muse, mutect2, varscan2
- APBA1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV55238263; called by muse, varscan2
- ASB4 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750596265; called by muse, mutect2, varscan2
- ATP13A2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 126/225 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764344537; called by muse, mutect2, varscan2
- C4orf54 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 104/176 reads (59%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); catalogued as COSV72767064; called by muse, mutect2, varscan2
- CCDC39 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 12/354 reads (3%) | catalogued as COSV56479007; called by muse, mutect2
- CHRNB4 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 129/290 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55715447; called by muse, mutect2, varscan2
- CLCN2 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 908/1359 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771299323, COSV55601161; called by muse, mutect2, varscan2
- CLEC4E | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 77/188 reads (41%) | catalogued as COSV55226819; called by muse, mutect2, varscan2
- CLIP1 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1426526590; called by muse, mutect2, varscan2
- CTNNA2 | c.1507A>G p.I503V | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); catalogued as rs1377768390; called by muse, mutect2, varscan2
- CTNND1 | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV62383870; called by muse, mutect2, varscan2
- DPP10 | c.125T>G p.I42S | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100068362; called by muse, mutect2, varscan2
- FCER2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs755933015; called by muse, mutect2, varscan2
- GLB1L | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs747707530; called by muse, mutect2, varscan2
- GSG1L2 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 61/478 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV52327476; called by muse, mutect2
- GTF3C1 | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 92/1083 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55183619; called by muse, mutect2
- HMBS | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0911046; called by muse, mutect2, varscan2
- IGLV1-36 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs532396053; called by muse, mutect2, varscan2
- IL16 | c.3276dup p.L1093Tfs*10 (on ENST00000302987 / NM_172217.5; = p.L392Tfs*10 on NM_004513.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 24/144 reads (17%) | catalogued as rs777448128; called by mutect2, varscan2
- IPO5 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 75/108 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1298135560; called by muse, mutect2, varscan2
- KCNJ12 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 85/462 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs755030830; called by muse, mutect2, varscan2
- KEAP1 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50565587; called by muse, mutect2, varscan2
- KRT72 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 356/1053 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs779414132; called by muse, mutect2, varscan2
- LRP1B | c.9524G>T p.R3175I | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV101257726; called by muse, mutect2, varscan2
- LRRTM4 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 67/185 reads (36%) | catalogued as rs1484615851, COSV69139560, COSV69139830; called by muse, mutect2, varscan2
- LUM | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 54/177 reads (31%) | catalogued as COSV57127483, COSV57127798; called by muse, mutect2, varscan2
- MRC1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 99/559 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1445835500; called by muse, mutect2, varscan2
- MTUS2 | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 105/171 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs1432651915; called by muse, mutect2, varscan2
- NADSYN1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as rs142449261; called by muse, mutect2, varscan2
- NAV3 | c.6749T>C p.V2250A (on ENST00000397909 / NM_001024383.2; = p.V2228A on NM_014903.6) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV57076289; called by muse, mutect2, varscan2
- NR6A1 | c.1261A>G p.I421V (on ENST00000487099 / NM_033334.4; = p.I416V on NM_001489.5) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775195028; called by muse, mutect2, varscan2
- NT5C1B | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV58398234; called by muse, mutect2, varscan2
- OR2M2 | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 67/279 reads (24%) | catalogued as COSV62897809, COSV62898568; called by muse, mutect2, varscan2
- OR2M2 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV100677226; called by muse, mutect2, varscan2
- OR2M2 | c.895A>G p.R299G | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100677182; called by muse, mutect2, varscan2
- OR2T34 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1479320964; called by muse, mutect2, varscan2
- OR52A1 | c.787_789del p.F263del | In Frame Del (DEL) | VAF 23/131 reads (18%) | catalogued as rs766997566; called by pindel, varscan2
- PEX5L | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV55850021; called by muse, mutect2
- PLD2 | c.903G>T p.W301C | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs748710430; called by muse, varscan2
- PRPSAP1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs771369497; called by muse, mutect2, varscan2
- PTK2 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150568425, COSV61787289; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as rs751434439, COSV54590426; called by muse, mutect2, varscan2
- RP1 | c.1807G>C p.D603H | Missense Mutation (SNP) | VAF 49/350 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV55125063; called by muse, mutect2, varscan2
- RUNX1T1 | c.1304G>A p.R435K (on ENST00000265814 / NM_001198628.1; = p.R408K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV56166353; called by muse, mutect2, varscan2
- RYR1 | c.8477C>A p.A2826D | Missense Mutation (SNP) | VAF 60/708 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100615723; called by muse, mutect2
- SF3B1 | c.2255A>T p.Y752F | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV59212391; called by muse, varscan2
- SLC44A1 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs761961178, COSV100570645; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1961C>T p.A654V (on ENST00000540229 / NM_001371097.1; = p.A593V on NM_001009562.4) | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as COSV67445651; called by muse, varscan2
- SP8 | c.1124C>T p.A375V (on ENST00000361443 / NM_198956.4; = p.A393V on NM_182700.6) | Missense Mutation (SNP) | VAF 74/655 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815323; called by muse, mutect2, varscan2
- SPEF2 | c.5131C>A p.P1711T | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.599); catalogued as COSV57433439; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 52/301 reads (17%) | PolyPhen benign (0.033); catalogued as COSV52536424; called by muse, mutect2, varscan2
- STAT4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 238/371 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs758217844; called by muse, mutect2, varscan2
- TAS2R8 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs780966630; called by muse, mutect2, varscan2
- TFEB | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs757546185, COSV57824976; called by muse, mutect2, varscan2
- TFRC | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs772407869; called by muse, mutect2
- TMEM132D | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 167/441 reads (38%) | catalogued as COSV70605643; called by muse, mutect2, varscan2
- TMEM52B | c.403C>G p.L135V (on ENST00000381923 / NM_001079815.1; = p.L115V on NM_153022.4) | Missense Mutation (SNP) | VAF 150/525 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.708); catalogued as COSV100046359; called by muse, mutect2, varscan2
- YJU2 | c.585C>T p.T195= | Splice Region (SNP) | VAF 44/128 reads (34%) | catalogued as rs527648441, COSV53608057; called by muse, varscan2
- ZBTB11 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 54/171 reads (32%) | catalogued as COSV100465609; called by muse, mutect2, varscan2
- ZNF536 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200453890, COSV62825016; called by muse, mutect2, varscan2
- ZNF99 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 72/414 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs530998365; called by muse, varscan2
- ADGRB1 | c.1436G>T p.C479F | Missense Mutation (SNP) | VAF 196/538 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHCYL2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 159/645 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ALDH3A1 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMOTL2 | c.619del p.R207Efs*12 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.1258A>G p.R420G | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- APOB | c.13450A>T p.T4484S | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- APOB | c.10706dup p.N3569Kfs*44 | Frame Shift Ins (INS) | VAF 94/362 reads (26%) | called by mutect2, pindel, varscan2
- APOB | c.3466G>A p.A1156T | Missense Mutation (SNP) | VAF 133/328 reads (41%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ASNS | c.756G>C p.R252S | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- BCHE | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BCL11B | c.1744G>T p.G582C (on ENST00000357195 / NM_001282237.2; = p.G511C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CACNA1A | c.5372T>C p.F1791S | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CCDC17 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- CENPS | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CFHR5 | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CRYBG2 | c.2771A>T p.E924V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CYB561A3 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DGKK | c.757-1G>T p.X253_splice | Splice Site (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- DLGAP4 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- EDIL3 | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML4 | c.2534dup p.N845Kfs*2 | Frame Shift Ins (INS) | VAF 19/124 reads (15%) | called by mutect2, pindel
- EML5 | c.2065G>T p.D689Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ERCC6L2 | c.2855dup p.N953Kfs*11 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- EYS | c.5287G>T p.E1763* | Nonsense Mutation (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- FAM135B | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FAT1 | c.6916_6928del p.R2306Lfs*26 | Frame Shift Del (DEL) | VAF 43/121 reads (36%) | called by mutect2, pindel, varscan2
- FSIP2 | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GCKR | c.1144-7G>T | Splice Region (SNP) | VAF 63/192 reads (33%) | called by muse, mutect2, varscan2
- GJD4 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 154/302 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- GREB1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM6 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERC2 | c.3004G>T p.G1002C | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ISM2 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ITGAM | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KAT14 | c.2185G>A p.G729S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- KAT6A | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KCNH7 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KIAA1217 | c.3569C>G p.S1190C | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KMT2D | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- KMT2D | c.1106del p.C369Lfs*33 | Frame Shift Del (DEL) | VAF 48/126 reads (38%) | called by mutect2, pindel*, varscan2*
- KRBOX4 | c.216del p.T73Pfs*21 (on ENST00000344302 / NM_001129898.2; = p.T73Pfs*16 on NM_017776.2) | Frame Shift Del (DEL) | VAF 42/101 reads (42%) | called by mutect2, pindel, varscan2
- KRT222 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT35 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- KSR2 | c.773T>A p.V258D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, varscan2
- L3MBTL3 | c.1703A>T p.H568L | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMP3 | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 94/571 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LDAH | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAGEC1 | c.2003A>T p.E668V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MAGEC2 | c.20T>G p.V7G | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MDGA2 | c.949G>T p.V317L (on ENST00000399232 / NM_001113498.2; = p.V19L on NM_182830.4) | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- METTL11B | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 122/319 reads (38%) | called by mutect2, varscan2
- MPZL2 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MS4A8 | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MUC17 | c.5195C>A p.T1732K | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC17 | c.10090C>T p.P3364S | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- NDC1 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NFIC | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 178/580 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOM1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NRBP1 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- NXF1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OPN1SW | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 95/472 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M3 | c.439T>C p.F147L | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- OR51B4 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- OR52E6 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PCDH11X | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PCDHA10 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 174/315 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PCNT | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 101/815 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE10A | c.990del p.E331Rfs*2 | Frame Shift Del (DEL) | VAF 45/145 reads (31%) | called by mutect2, pindel, varscan2
- PDE4B | c.2125T>C p.C709R | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PDGFRA | c.367+1G>A p.X123_splice | Splice Site (SNP) | VAF 68/148 reads (46%) | called by muse, mutect2, varscan2
- PHACTR2 | c.1199G>T p.C400F | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLD2 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, varscan2
- PSG9 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 100/164 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PTK7 | c.3155C>G p.P1052R | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRO | c.160T>A p.S54T | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RANBP2 | c.2560G>C p.G854R | Missense Mutation (SNP) | VAF 114/455 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- REV3L | c.9090A>T p.K3030N | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- RIOX2 | c.950A>G p.D317G (on ENST00000333396 / NM_001042533.2; = p.D316G on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/395 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RIT2 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTBDN | c.170-2A>G p.X57_splice (on ENST00000393233 / NM_001270444.1; = p.X89_splice on NM_031429.2) | Splice Site (SNP) | VAF 76/214 reads (36%) | called by muse, mutect2, varscan2
- RXFP2 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 74/442 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN9A | c.2057G>A p.R686K (on ENST00000303354; = p.R675K on NM_002977.3) | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2
- SERPING1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 122/370 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SF3B1 | c.2254T>A p.Y752N | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); called by muse, varscan2
- SLC15A2 | c.1306A>C p.N436H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC15A4 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC22A6 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC32A1 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 148/444 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SOX30 | c.2125A>C p.N709H | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPHKAP | c.4136G>A p.C1379Y | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ST18 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SYT10 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THAP5 | c.880G>C p.E294Q (on ENST00000415914 / NM_001130475.3; = p.E252Q on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/270 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- TJP1 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TMEM115 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNR | c.1305G>A p.W435* | Nonsense Mutation (SNP) | VAF 68/250 reads (27%) | called by muse, mutect2, varscan2
- TTLL11 | c.1876T>A p.F626I | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3564C>A p.D1188E | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR97 | c.3345G>T p.W1115C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZNF407 | c.3915T>A p.N1305K | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF480 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF568 | c.1754C>A p.P585H | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF616 | c.1903T>G p.C635G | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF676 | c.1019C>G p.P340R (on ENST00000650058; = p.P308R on NM_001001411.3) | Missense Mutation (SNP) | VAF 149/631 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZSCAN26 | c.1353G>C p.Q451H (on ENST00000623276 / NM_001111039.2; = p.Q317H on NM_152736.5) | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); called by muse, mutect2
- ZXDB | c.922dup p.L308Pfs*52 | Frame Shift Ins (INS) | VAF 56/145 reads (39%) | called by mutect2, pindel, varscan2
- ACADS | c.63C>T p.A21= | Silent (SNP) | VAF 149/465 reads (32%) | called by muse, mutect2, varscan2
- ANK3 | c.7980C>G p.P2660= | Silent (SNP) | VAF 88/194 reads (45%) | catalogued as rs1564795708, COSV55050187; called by muse, mutect2, varscan2
- ATAD3A | c.729G>A p.A243= | Silent (SNP) | VAF 197/346 reads (57%) | catalogued as rs549678655, COSV59233195; called by muse, mutect2, varscan2
- ATP5F1B | c.1344G>A p.E448= | Silent (SNP) | VAF 121/359 reads (34%) | catalogued as rs888471798, COSV51634247; called by muse, mutect2, varscan2
- BCHE | c.915A>C p.A305= | Silent (SNP) | VAF 58/259 reads (22%) | catalogued as COSV100012804; called by muse, mutect2, varscan2
- C15orf39 | c.2919G>T p.P973= | Silent (SNP) | VAF 58/232 reads (25%) | called by muse, mutect2, varscan2
- C1orf141 | c.255G>A p.E85= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- CENPB | c.312G>A p.A104= | Silent (SNP) | VAF 146/395 reads (37%) | called by muse, mutect2, varscan2
- CSMD1 | c.3009G>C p.S1003= (on ENST00000520002; = p.S1002= on NM_033225.6) | Silent (SNP) | VAF 72/658 reads (11%) | called by muse, mutect2, varscan2
- EVL | c.1146G>A p.R382= (on ENST00000402714 / NM_001330221.2; = p.R384= on NM_016337.3) | Silent (SNP) | VAF 70/140 reads (50%) | called by muse, mutect2, varscan2
- FAM160A1 | c.663C>T p.F221= | Silent (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- FFAR3 | c.330C>T p.S110= | Silent (SNP) | VAF 133/1265 reads (11%) | called by muse, mutect2, varscan2
- HEG1 | c.1026G>T p.T342= | Silent (SNP) | VAF 119/276 reads (43%) | called by muse, mutect2, varscan2
- HEPACAM | c.612C>T p.I204= | Silent (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- INSYN2B | c.255G>A p.R85= | Silent (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- LILRB5 | c.723C>T p.T241= | Silent (SNP) | VAF 58/236 reads (25%) | called by muse, mutect2, varscan2
- MSANTD2 | c.1545T>C p.C515= (on ENST00000374979 / NM_001308027.2; = p.C463= on NM_024631.4) | Silent (SNP) | VAF 55/197 reads (28%) | called by muse, mutect2, varscan2
- NCKAP5 | c.2799A>T p.P933= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- NRK | c.3402A>T p.I1134= | Silent (SNP) | VAF 43/64 reads (67%) | called by muse, mutect2, varscan2
- OR5H15 | c.795G>T p.P265= | Silent (SNP) | VAF 112/496 reads (23%) | catalogued as rs371915983; called by muse, mutect2, varscan2
- OSTM1 | c.93C>G p.G31= | Silent (SNP) | VAF 118/436 reads (27%) | called by muse, mutect2, varscan2
- PDPR | c.1509G>A p.K503= | Silent (SNP) | VAF 45/202 reads (22%) | called by muse, mutect2, varscan2
- PLEKHO2 | c.1161C>A p.R387= | Silent (SNP) | VAF 41/216 reads (19%) | called by muse, mutect2, varscan2
- SCN8A | c.1494G>A p.R498= | Silent (SNP) | VAF 39/136 reads (29%) | called by muse, mutect2, varscan2
- SELENOK | c.138G>A p.V46= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100212599; called by muse, mutect2, varscan2
- SF3B1 | c.2253G>T p.G751= | Silent (SNP) | VAF 27/208 reads (13%) | called by muse, varscan2
- SMYD1 | c.357C>T p.T119= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs779230496; called by mutect2, varscan2
- SOX15 | c.399C>A p.R133= | Silent (SNP) | VAF 33/215 reads (15%) | called by muse, mutect2, varscan2
- TLK2 | c.1902A>G p.T634= (on ENST00000326270 / NM_001284333.2; = p.T612= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs767032124; called by muse, mutect2, varscan2
- TMEM31 | c.411G>A p.K137= | Silent (SNP) | VAF 45/130 reads (35%) | called by muse, mutect2, varscan2
- TRIM51 | c.1023T>C p.Y341= | Silent (SNP) | VAF 18/458 reads (4%) | catalogued as COSV55271480; called by muse, mutect2
- TTN | c.23655G>A p.V7885= (on ENST00000591111; = p.V6958= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as COSV60078851; called by muse, mutect2, varscan2
- WDR19 | c.2505C>G p.L835= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV56464188; called by muse, mutect2, varscan2
- ZBTB11 | c.417G>A p.L139= | Silent (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- ZNF506 | c.873C>A p.G291= | Silent (SNP) | VAF 68/377 reads (18%) | called by muse, mutect2, varscan2
- ZNF768 | c.1062C>T p.F354= | Silent (SNP) | VAF 98/573 reads (17%) | catalogued as rs1459483118, COSV63323499; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83419C>A | Intron (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- CABIN1 | c.4747-8424C>G | Intron (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-3554G>T | Intron (SNP) | VAF 92/559 reads (16%) | called by muse, mutect2, varscan2
- KLRA1P | n.149C>T | RNA (SNP) | VAF 41/261 reads (16%) | catalogued as rs267603281; called by muse, mutect2, varscan2
- LMO3 | chr12:16605784 C>A | 5'Flank (SNP) | VAF 62/198 reads (31%) | called by muse, mutect2, varscan2
- NOL8 | c.282-797G>A | Intron (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157655 G>T | 5'Flank (SNP) | VAF 40/118 reads (34%) | catalogued as rs371282250; called by muse, varscan2
- REXO4 | c.572+300G>A | Intron (SNP) | VAF 12/58 reads (21%) | catalogued as rs1274236594; called by muse, mutect2, varscan2
- SERPINA13P | n.742C>T | RNA (SNP) | VAF 26/155 reads (17%) | catalogued as rs765683104; called by muse, mutect2, varscan2
- SLIT2 | c.179+1052C>A | Intron (SNP) | VAF 64/272 reads (24%) | called by muse, mutect2, varscan2
- TAZ | c.*173A>T | 3'UTR (SNP) | VAF 121/158 reads (77%) | called by muse, mutect2, varscan2
- TMEM116 | c.-118T>G | 5'UTR (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071155 C>T | 3'Flank (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- ZBP1 | c.*152G>A | 3'UTR (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2, varscan2
- ZNF44 | c.*154A>T | 3'UTR (SNP) | VAF 47/126 reads (37%) | called by muse, mutect2, varscan2
